Surgical pathology report (de-identified scan), TCGA case TCGA-55-8615, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8615-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Pre-Op Diagnosis
Right lung mass
Post-Op Diagnosis
Same
Clinical History
Nothing indicated on requisition
Gross Description:
Five parts

Container labeled [REDACTED] - level 9 lymph node" is a 1.0 x 0.8 x 0.5 cm nodular portion of gray tan fleshy tissue surrounded by yellow adipose tissue. The specimen is bisected and entirely submitted in a single cassette.

Container labeled [REDACTED] - level 8 lymph node" are 1.5 x 1.0 x 0.4 cm of tan gray to yellow fibroadipose appearing tissue fragments which are entirely submitted in a single cassette.

Container labeled [REDACTED] - right lung" is 757 gram previously partially sectioned portion of pulmonary parenchyma grossly consistent with right lung. The specimen as received measures 18.8 x 17.4 x 8.8 cm and has a bronchial margin across the primary bronchus at a point 0.4 cm from the bifurcation of the secondary bronchi. Surrounding the bronchial margin are seven well defined gray tan to brown nodules measuring from 0.5 to 2.6 cm in greatest dimension. The pleura is wrinkled, moderately anthracotic streaked, and gray red to brown. On the middle lobe extending to the upper pole and to the lower pole on the anterolateral aspect there is an area which is previously sectioned to reveal a fairly well defined lobulated friable necrotic gray tan lesion which occupies much of the lower lobe and lateral lower aspect including the lower lobe and middle lobe. This overall measures approximately

[REDACTED]

[page 2 of 3]
9.5 x 8.5 x 6.5 cm. The lesion is seen at its nearest point 2.6 cm from the nearest bronchial margin extending into the lower lobe. The bronchial connection is grossly identified. The lesion grossly appears to extend to within 0.1 cm of the basal, lateral, and lower medial pleura; however, the lesion does not grossly appear to extend through the pleura. The lesion abuts on the pulmonary artery. The lesion grossly abuts the pulmonary vasculature and adheres to it but does not grossly appear to extend through the vascular wall. The specimen has been previously partially sectioned to reveal the lesion for tissue harvest for genomic studies. Within the specimen container are three tissue cassettes each labeled [REDACTED]. The remaining uninvolved parenchyma is spongy and congested with moderate anthracotic streaking. Adjacent to the lesion extending to the pleura in several areas there are multiple adjacent apparently separate tumor nodules with similar consistency measuring up to 1.2 cm. Representative sections are submitted labeled as follows: A - shaved bronchial margin, B through F - individual peribronchial nodules bisected, G - whole smaller peribronchial nodules, H - representative lesion to bronchial connection, I - representative lesion to medial pleura, J - representative lesion to basal pleura, K - representative lesion to lateral pleura, L and M - representative lesion to pulmonary vasculature, N - random lesion, O - representative uninvolved upper lobe parenchyma, P - representative middle lobe parenchyma, Q - representative lower lobe parenchyma.

Container labeled [REDACTED] level 7 lymph node" are three fairly well defined nodules of rubbery gray brown to black fleshy tissue from 0.9 to 1.6 cm in greatest dimension each. Each is bisected and individually submitted in three cassettes.

Container labeled [REDACTED] 5 - level 4R lymph node" are 2.6 x 2.0 x 1.1 cm of shaggy to lobulated gray tan to yellow brown fibroadipose and fleshy appearing tissue fragments which are entirely submitted in two cassettes.

[REDACTED]

Microscopic Description:

Reviewed are slides labeled [REDACTED]

Final Diagnosis

Lymph node, level 9, right lung:

One lymph node negative for metastatic carcinoma (0/1).

Lymph node, level 8, right lung, excision:

Multiple fragments of benign lymph node negative for metastatic carcinoma (0/1).

Lung, right, pneumonectomy:

Tumor characteristics:

Specimen integrity: Intact.

Specimen laterality: Right lung.

Histologic type: Adenocarcinoma.

Histologic grade: Moderately differentiated.

Tumor site: Tumor involves middle lobe.

Tumor focality: Grossly distinct tumor nodules in same lobe (see comment).

Tumor size: 9.5 x 8.5 x 6.5 cm in overall dimension.

Visceral pleural invasion: Tumor extends into but not through elastic layer (PL0).

Lymphovascular space invasion: Present.

Tumor extension: Tumor confined to middle lobe.

[REDACTED]

[page 3 of 3]
Treatment effect: Not identified.

Surgical margin status:

Tumor distance from bronchial margin: 2.6 cm.

Tumor distance from pleural surface: Less than 1 mm.

Lymph node status:

Total number of lymph nodes received with pneumonectomy specimen (excluding separately submitted lymph nodes): 10.

Total number of lymph nodes containing metastatic carcinoma: 5 (5/10).

Other:

Stage: pT3N2

Lymph node, level 7, excision:

Metastatic carcinoma involving one of three lymph nodes (1/3).

Lymph node, level 4R, excision:

Multiple fragments of lymph node negative for metastatic carcinoma:
0/7 PAS 9 SPC-A

Comments

Histologic sections from the 9.5 cm mass demonstrates a moderately differentiated adenocarcinoma with a heterogenous appearance. In areas, the cells are tall columnar with areas of necrosis. In other areas prominent mucinous differentiation is seen with features morphologically suggestive of bronchial alveolar type. A limited panel of immunohistochemical stains is performed with working controls and demonstrates the cells to be positive for TTF1 and CK7 and negative for CK20. These findings support the diagnosis of primary lung malignancy.

An elastin stain is performed with working controls and highlights rare neoplastic cells extending into but not entirely through the elastic layer; however, based on size this is best classified as a pT3.

A total of 22 lymph nodes are identified including all parts, six of which contain metastatic carcinoma.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED] has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] [REDACTED] qualified to perform high complexity clinical laboratory testing.

Original report signed out by Dr. [REDACTED]

REVISION:

Stage changed to reflect the above.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 947fef60-df34-4a9d-9548-91858c7a17bc (TCGA-55-8615.37B4238A-1AEA-4670-8C43-B24525B94CDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).